Somatic mutation profile of tumor specimen ALCH-B0DX-TTP1-A (aliquot ALCH-B0DX-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0DX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.6 years (27,985 days).
Specimen ALCH-B0DX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba819a0-3ccd-48bd-a493-fc904f3499b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0DX-NB1-A (Blood Derived Normal), aliquot ALCH-B0DX-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd5ba429-0760-402e-913a-b400801b1826

The open-access MAF lists 163 somatic variants for this specimen: 119 protein-altering or splice-affecting, 29 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 29, Nonsense Mutation 9, Intron 8, 3'UTR 4, Splice Site 3, RNA 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.939+1169C>G | Intron (SNP) | VAF 41/668 reads (6%) | catalogued as rs1057519791, COSV100336065; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.493-2A>C p.X165_splice | Splice Site (SNP) | VAF 43/290 reads (15%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV66581181; called by muse, mutect2
- ATP1A2 | c.1643G>C p.R548P | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM054647; called by muse, mutect2, varscan2
- BEND4 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 19/426 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV72469112; called by muse, mutect2
- CACNA1C | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.584); catalogued as COSV100223776, COSV59776167; called by muse, mutect2
- CEACAM18 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 21/417 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67283933; called by muse, mutect2
- COL6A3 | c.2497+2T>G p.X833_splice | Splice Site (SNP) | VAF 17/221 reads (8%) | catalogued as COSV55090438; called by muse, mutect2
- FSCN2 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV58366878; called by muse, mutect2, varscan2
- GRIN2A | c.3879T>A p.D1293E | Missense Mutation (SNP) | VAF 79/682 reads (12%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV58037286; called by muse, mutect2, varscan2
- HAPLN2 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as rs1223649049; called by muse, mutect2, varscan2
- INO80D | c.2920C>A p.Q974K | Missense Mutation (SNP) | VAF 29/612 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV68960012; called by muse, mutect2
- LAIR1 | c.454C>G p.H152D | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV57305675, COSV57306539; called by muse, mutect2
- LHX9 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.52); catalogued as rs1381465977, COSV61329787; called by muse, mutect2, varscan2
- LILRB4 | c.454A>T p.T152S | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs752763780; called by muse, mutect2
- LRRK2 | c.5106G>T p.M1702I | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV100111376; called by muse, mutect2
- MGAT5B | c.1483G>A p.V495M (on ENST00000569840 / NM_001199172.2; = p.V493M on NM_144677.3) | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200878515; called by muse, mutect2, varscan2
- MMP13 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.413); catalogued as COSV52826122; called by muse, mutect2, varscan2
- MPRIP | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs532340942; called by muse, mutect2, varscan2
- PPRC1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs759964876; called by muse, mutect2
- PRRC2C | c.2250G>A p.M750I (on ENST00000367742; = p.M748I on NM_015172.4) | Missense Mutation (SNP) | VAF 23/442 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV58915150; called by muse, mutect2
- REV3L | c.7213G>A p.E2405K | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62618494; called by muse, mutect2
- SERPINA12 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.219); catalogued as rs375689801, COSV57944012; called by muse, mutect2, varscan2
- SLC29A4 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV51873644; called by muse, mutect2
- SMLR1 | c.83T>C p.M28T | Missense Mutation (SNP) | VAF 48/576 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1021058312; called by muse, mutect2
- SSX7 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 29/163 reads (18%) | catalogued as rs782803891, COSV99993753; called by muse, mutect2, varscan2
- STAG2 | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54354600; called by muse, mutect2, varscan2
- SYNE1 | c.9419C>T p.A3140V (on ENST00000367255 / NM_182961.4; = p.A3147V on NM_033071.3) | Missense Mutation (SNP) | VAF 78/548 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs146402274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYS1 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV54781561; called by muse, mutect2
- TBX21 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1202556633, COSV99456040; called by muse, mutect2
- TDRD3 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99541167; called by muse, varscan2
- ZFR | c.1327A>G p.T443A | Missense Mutation (SNP) | VAF 167/636 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1317871543; called by muse, mutect2, varscan2
- ZNF43 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as rs1375825451; called by muse, mutect2
- ABCG5 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 99/965 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AC007040.2 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACSM4 | c.1174A>G p.M392V | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ADGB | c.3612G>C p.K1204N | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- AFF3 | c.2982+1G>T p.X994_splice | Splice Site (SNP) | VAF 31/234 reads (13%) | called by muse, mutect2, varscan2
- AP4B1 | c.1859T>A p.L620Q | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10D | c.2718A>G p.I906M | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BLM | c.2497G>T p.A833S | Missense Mutation (SNP) | VAF 37/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C1QL3 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD4A | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CDH18 | c.1169T>C p.M390T | Missense Mutation (SNP) | VAF 30/579 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- CENPE | c.6296G>C p.R2099T | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CSHL1 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 118/545 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CTNND2 | c.3113C>A p.A1038D | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2
- DDX54 | c.2145G>C p.L715F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2
- DNAH6 | c.3835G>C p.E1279Q | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- DNTTIP2 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.125); called by muse, mutect2
- EMILIN2 | c.2221G>A p.V741I | Missense Mutation (SNP) | VAF 15/424 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2
- EML4 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2
- EVX2 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FAM160A1 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- FOXG1 | c.1292G>C p.S431T | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- GPR63 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- HIP1 | c.1407C>G p.S469R | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.148); called by muse, mutect2
- ICE1 | c.3347G>A p.C1116Y | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IFNAR1 | c.1249A>T p.K417* | Nonsense Mutation (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- IL21 | c.353A>T p.H118L | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- ILDR2 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2
- IRAK4 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- KCNH2 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF1A | c.4016A>T p.H1339L (on ENST00000320389 / NM_001379639.1; = p.H1331L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.06); called by muse, mutect2
- KLHL1 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.052); called by muse, varscan2
- KLHL11 | c.1368T>A p.Y456* | Nonsense Mutation (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- LAMA2 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- LRP2 | c.10860G>T p.E3620D | Missense Mutation (SNP) | VAF 70/807 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- MAP1LC3B2 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MARCO | c.1160A>T p.K387M | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- MDM4 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2
- MFN2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 37/485 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MTMR8 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH1 | c.4910A>C p.N1637T | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- NEB | c.1417C>G p.Q473E | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); called by muse, mutect2
- NIN | c.1727C>G p.P576R | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOL8 | c.732G>C p.E244D | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- NOX3 | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP205 | c.5327A>T p.Q1776L | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, varscan2
- OR10G7 | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2
- OR4Q2 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- OR51S1 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PACS1 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2
- PACSIN3 | c.532A>T p.S178C | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PAN2 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2
- PARVG | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCLO | c.15017A>T p.Q5006L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.6067G>T p.V2023F | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLA2G7 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 46/413 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA8 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- PUM1 | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- REG3A | c.13A>T p.M5L | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ROBO3 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- ROBO3 | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.139); called by muse, mutect2
- SI | c.3168T>A p.S1056R | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC9A2 | c.1331C>A p.A444E | Missense Mutation (SNP) | VAF 75/684 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- SOX6 | c.1460C>T p.P487L (on ENST00000528429 / NM_001145819.2; = p.P460L on NM_017508.3) | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPATA13 | c.1900A>T p.K634* | Nonsense Mutation (SNP) | VAF 33/238 reads (14%) | called by muse, mutect2, varscan2
- SPG11 | c.1814A>T p.H605L | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SPTB | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 109/702 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- STARD9 | c.4202G>T p.G1401V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.137); called by muse, mutect2
- STRA8 | c.778A>G p.S260G (on ENST00000275764; = p.S238G on NM_182489.2) | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- STXBP5 | c.3392C>G p.S1131* (on ENST00000321680 / NM_001127715.2; = p.S1095* on NM_139244.4) | Nonsense Mutation (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
- TERB1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TJP1 | c.5029C>G p.R1677G | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53BP2 | c.1661G>C p.G554A (on ENST00000343537 / NM_001031685.3; = p.G425A on NM_005426.2) | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV19 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); called by muse, mutect2
- TUT4 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- TWIST1 | c.56A>C p.N19T | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- URB1 | c.1356G>T p.R452S | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- VARS1 | c.1664G>C p.R555T | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VWA5A | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2
- WDR33 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- WNK2 | c.5005C>T p.R1669* (on ENST00000297954 / NM_001282394.1; = p.R1632* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- ZDBF2 | c.4748G>T p.R1583I | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ZFHX4 | c.4990C>A p.H1664N | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.069); called by muse, mutect2
- ZNF479 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF507 | c.1785A>T p.R595S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- ZNF600 | c.767del p.G256Vfs*7 | Frame Shift Del (DEL) | VAF 27/246 reads (11%) | called by mutect2, varscan2
- ZNF99 | c.2278C>G p.P760A | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADAMTSL1 | c.1974G>A p.L658= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs1177777251; called by muse, mutect2
- ADGRL3 | c.1563G>A p.R521= (on ENST00000506720 / NM_001322402.2; = p.R453= on NM_015236.6) | Silent (SNP) | VAF 41/404 reads (10%) | catalogued as COSV101547014; called by muse, mutect2, varscan2
- ALG9 | c.117G>A p.A39= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CAMK2A | c.310C>A p.R104= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- CCT8L2 | c.675T>A p.S225= | Silent (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- CLCN2 | c.1095C>G p.L365= | Silent (SNP) | VAF 30/504 reads (6%) | called by muse, mutect2
- CNTN2 | c.1935T>A p.A645= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- DMP1 | c.517C>A p.R173= | Silent (SNP) | VAF 34/235 reads (14%) | called by muse, mutect2, varscan2
- EFL1 | c.2541A>G p.V847= | Silent (SNP) | VAF 42/333 reads (13%) | catalogued as rs747863769; called by muse, mutect2, varscan2
- FAT3 | c.3417A>G p.E1139= | Silent (SNP) | VAF 54/472 reads (11%) | catalogued as COSV53105607; called by muse, mutect2, varscan2
- FLI1 | c.915C>A p.T305= | Silent (SNP) | VAF 27/258 reads (10%) | catalogued as rs1224911315; called by muse, mutect2
- FOXA3 | c.402G>T p.P134= | Silent (SNP) | VAF 48/345 reads (14%) | called by muse, mutect2, varscan2
- GON4L | c.1767G>C p.L589= | Silent (SNP) | VAF 31/564 reads (5%) | catalogued as COSV55191690; called by muse, mutect2
- HOXB7 | c.123G>C p.P41= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- HPS4 | c.1329C>T p.L443= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as rs762613783, COSV61102491; called by muse, mutect2
- HSPA1L | c.1245G>C p.L415= | Silent (SNP) | VAF 32/487 reads (7%) | called by muse, mutect2
- MAGEE1 | c.1386G>C p.L462= | Silent (SNP) | VAF 13/241 reads (5%) | called by muse, mutect2
- NPAS3 | c.1311G>A p.E437= (on ENST00000356141 / NM_001164749.2; = p.E405= on NM_022123.3) | Silent (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- OR6Y1 | c.48T>A p.R16= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100225565; called by muse, mutect2
- PRDM13 | c.573C>G p.S191= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- SELENOV | c.405G>T p.R135= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- SLC6A15 | c.969C>T p.Y323= | Silent (SNP) | VAF 46/509 reads (9%) | called by muse, mutect2
- STAG2 | c.1110G>T p.R370= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- TACR3 | c.660T>A p.L220= | Silent (SNP) | VAF 49/440 reads (11%) | called by muse, mutect2, varscan2
- TDO2 | c.138G>T p.L46= | Silent (SNP) | VAF 34/181 reads (19%) | called by muse, varscan2
- TERB1 | c.936A>C p.G312= | Silent (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.1017T>C p.Y339= | Silent (SNP) | VAF 28/220 reads (13%) | catalogued as rs756289824; called by muse, mutect2, varscan2
- ZFHX4 | c.4989C>A p.T1663= | Silent (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- ZIM2 | c.1293C>G p.L431= | Silent (SNP) | VAF 13/456 reads (3%) | catalogued as COSV55632878; called by muse, mutect2
- ADGRE4P | n.546G>C | RNA (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- CPLANE1 | c.*50G>T | 3'UTR (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- CSF2RA | c.*45A>T | 3'UTR (SNP) | VAF 56/599 reads (9%) | called by muse, mutect2
- DLG2 | c.205-65794G>A | Intron (SNP) | VAF 16/171 reads (9%) | catalogued as rs552998302, COSV54619672; called by muse, mutect2
- DUOX2 | c.513+20G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs919550468; called by muse, mutect2, varscan2
- EXOC5 | c.*2621G>A | 3'UTR (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- FGFR1 | c.358+360G>C | Intron (SNP) | VAF 34/480 reads (7%) | called by muse, mutect2
- FOXP1 | c.975-22G>C | Intron (SNP) | VAF 42/337 reads (12%) | catalogued as rs753162341; called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65680C>G | Intron (SNP) | VAF 42/460 reads (9%) | catalogued as COSV58246929; called by muse, mutect2
- PPIH | chr1:42658413 C>T | 5'Flank (SNP) | VAF 33/329 reads (10%) | called by muse, mutect2, varscan2
- PTPRB | c.5025-32C>A | Intron (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.4271G>C | RNA (SNP) | VAF 10/80 reads (13%) | called by muse, varscan2
- TGFBR3 | c.*1577A>C | 3'UTR (SNP) | VAF 44/403 reads (11%) | called by muse, mutect2, varscan2
- VWA5B1 | c.2133+174A>T | Intron (SNP) | VAF 33/382 reads (9%) | called by muse, mutect2
